Gene-level copy-number profile of tumor specimen TCGA-BR-8687-01A from TCGA case TCGA-BR-8687, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.0 years (24,472 days).
Specimen TCGA-BR-8687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.cc98e705-3749-437d-96be-18c5f4e97653.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8687-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c41f130c-6fb2-45a6-acf9-70c0919836a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 93; copy number 2: 199; copy number 3: 23,970; copy number 4: 28,308; copy number 5: 4,273; copy number 6: 2,245; copy number 7: 168; copy number 8: 120; copy number 9: 48; copy number 13: 20; copy number 14: 16; copy number 17: 26; copy number 18: 19; copy number 20: 7; copy number 23: 83; copy number 25: 46; copy number 26: 62; copy number 27: 53; copy number 30: 1; copy number 32: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8687-01A-11D-2390-01): tumor purity 0.62, ploidy 2.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 435 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:69,641,156–71,452,868, 40 genes, copy number 9: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1.
- chr12:38,078,529–38,274,549, 10 genes, copy number 27: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA.
- chr12:52,948,871–53,102,345, 8 genes, copy number 9: KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6.
- chr12:55,900,300–56,163,496, 26 genes, copy number 17: GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6.
- chr12:59,596,029–62,622,213, 29 genes, copy number 18–30 (within-gene range 5–30): SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2.
- chr12:64,497,968–67,069,162, 56 genes, copy number 26 (within-gene range 3–26): AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:67,269,358–67,590,771, 7 genes, copy number 20 (within-gene range 3–20): CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442.
- chr12:67,989,445–68,234,686, 1 gene, copy number 26 (within-gene range 5–26): IFNG-AS1.
- chr12:68,143,318–68,332,381, 5 genes, copy number 26 (within-gene range 7–26): AC007458.1, IFNG, IL26, IL22, MDM1.
- chr12:68,552,995–68,576,136, 2 genes, copy number 27: RPSAP12, Metazoa_SRP.
- chr12:68,626,870–68,627,375, 2 genes, copy number 27: RPL10P12, SNORA70G.
- chr12:68,746,125–70,920,738, 46 genes, copy number 25: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr20:51,902,291–54,651,169, 39 genes, copy number 27: RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.
- chr20:56,412,112–56,786,087, 16 genes, copy number 14 (within-gene range 8–14): CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:57,351,223–59,259,113, 54 genes, copy number 32 (within-gene range 8–32): RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831.
- chr20:61,077,224–63,180,903, 74 genes, copy number 23 (broad region; genes not listed).
- chr20:63,939,829–63,956,416, 1 gene, copy number 13 (within-gene range 8–13): UCKL1.
- chr20:63,953,384–64,313,132, 19 genes, copy number 13: UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 93. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
